Somatic mutation profile of tumor specimen C3N-03911-01 (aliquot CPT0223610006) from CPTAC case C3N-03911, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 71.0 years (25,935 days).
Specimen C3N-03911-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 712026c8-4065-48d7-b56b-5128bed595f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03911-71 (Blood Derived Normal), aliquot CPT0223730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90d7402f-6589-4050-974f-218e5539103b

The open-access MAF lists 42 somatic variants for this specimen: 26 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Nonsense Mutation 2, Frame Shift Del 2, 3'UTR 2, RNA 1, Intron 1, 5'UTR 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 96/773 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 21/505 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CC2D1A | c.945C>T p.P315= | Splice Region (SNP) | VAF 14/140 reads (10%) | catalogued as rs778117971; called by muse, mutect2
- CPT1C | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1243005888, COSV54921130, COSV54922438; called by muse, mutect2
- DCHS1 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs759188370, COSV55032458; called by muse, mutect2
- ESRP2 | c.1703G>A p.G568D (on ENST00000565858 / NM_001365264.1; = p.G558D on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/541 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1212384012; called by muse, mutect2, varscan2
- F8 | c.4999C>T p.R1667W | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs782562155, CD034859, COSV64275614; called by muse, mutect2
- GLUD2 | c.1540A>G p.M514V | Missense Mutation (SNP) | VAF 48/737 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs749289372; called by muse, mutect2
- HYDIN | c.12304G>T p.A4102S | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV66642415; called by muse, mutect2
- KCNK6 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.439); catalogued as rs1175463882; called by muse, mutect2
- MROH2A | c.4277G>A p.R1426Q | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as rs926769077; called by muse, mutect2, varscan2
- NEK5 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140291042, COSV62879763; called by muse, mutect2, varscan2
- ADGRL2 | c.2290C>T p.R764* (on ENST00000370717 / NM_001366005.1; = p.R751* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 14/263 reads (5%) | called by muse, mutect2
- APOH | c.876T>A p.H292Q | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ASH1L | c.4669G>T p.V1557F | Missense Mutation (SNP) | VAF 61/545 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CHD1L | c.1766_1767del p.R589Kfs*4 | Frame Shift Del (DEL) | VAF 20/123 reads (16%) | called by mutect2, pindel, varscan2
- EPHA6 | c.318del p.Q106Hfs*9 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel
- EVX1 | c.1112C>A p.T371N | Missense Mutation (SNP) | VAF 118/743 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- FRMD4A | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2
- HDX | c.1878C>G p.Y626* | Nonsense Mutation (SNP) | VAF 24/179 reads (13%) | called by muse, mutect2, varscan2
- MUC16 | c.31759G>C p.D10587H | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2
- PHLDA2 | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 12/381 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM10 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 84/523 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- RNF4 | c.144C>G p.D48E | Missense Mutation (SNP) | VAF 10/340 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2
- SLC36A4 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.135); called by muse, mutect2
- STEAP3 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2
- AKAP12 | c.5094T>C p.D1698= | Silent (SNP) | VAF 12/157 reads (8%) | called by muse, mutect2
- ARSF | c.228C>T p.S76= | Silent (SNP) | VAF 49/349 reads (14%) | called by muse, mutect2, varscan2
- GYG2 | c.990G>A p.P330= | Silent (SNP) | VAF 24/590 reads (4%) | catalogued as rs775608722, COSV58551674; called by muse, mutect2
- KDM6B | c.4683C>T p.I1561= | Silent (SNP) | VAF 38/636 reads (6%) | catalogued as COSV54680362, COSV99640850; called by muse, mutect2
- NAA25 | c.459G>A p.V153= | Silent (SNP) | VAF 27/248 reads (11%) | called by muse, mutect2, varscan2
- OR11G2 | c.909G>A p.K303= | Silent (SNP) | VAF 26/254 reads (10%) | catalogued as COSV100639963; called by muse, mutect2, varscan2
- PSAP | c.1227C>T p.C409= | Silent (SNP) | VAF 36/922 reads (4%) | catalogued as rs147030327; called by muse, mutect2
- PTPRN2 | c.2560C>A p.R854= | Silent (SNP) | VAF 15/110 reads (14%) | catalogued as COSV66104687; called by muse, mutect2, varscan2
- RGS18 | c.654A>G p.S218= | Silent (SNP) | VAF 46/235 reads (20%) | catalogued as rs756990511; called by muse, mutect2, varscan2
- RPRD2 | c.1440A>G p.P480= | Silent (SNP) | VAF 22/476 reads (5%) | called by muse, mutect2
- ALDH3A1 | chr17:19748369 A>T | 5'Flank (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- CCDC22 | c.*161G>A | 3'UTR (SNP) | VAF 34/355 reads (10%) | called by muse, mutect2
- KRT6B | c.-14C>A | 5'UTR (SNP) | VAF 55/880 reads (6%) | called by muse, mutect2
- MLX | c.*1580C>A | 3'UTR (SNP) | VAF 42/881 reads (5%) | called by muse, mutect2
- OR2L1P | n.914C>A | RNA (SNP) | VAF 20/534 reads (4%) | called by muse, mutect2
- ZCWPW1 | c.361+17G>C | Intron (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
